Surgical pathology report (de-identified scan), TCGA case TCGA-FU-A3YQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FU-A3YQ-01A (Primary Tumor).

[page 1 of 3]
Sex: Female

Collected:

Received:

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right ovary and fallopian tube, excision:
Surface serous adenofibroma.
Additional cystic follicles.
Fallopian tube without significant pathologic abnormality.

- B. Left ovary and fallopian tube, excision:
Involuting corpus luteum.
Cystic follicles.
Hemorrhagic corpus luteum.
Fallopian tube without significant pathologic abnormality.

C. Radical hysterectomy:

Tumor Characteristics:

1. Histologic type: Squamous cell carcinoma.
2. Histologic grade: Well differentiated, Grade 1.
3. Tumor site: Cervix.
4. Tumor size: 1.7 x 1.7 cm.
5. Stromal invasion: Tumor extends a depth of 0.8 cm into a 1.8 cm thick cervical wall, as measured microscopically.
6. Lymphovascular space invasion: Focally present.

Surgical Margin Status:

1. Vaginal mucosal margin: Negative.
2. Deep margin: Negative.

Lymph Node Status:

See parts E through J.

Other:

1. Endometrium without evidence of malignancy.
2. Myometrium without evidence of malignancy.
3. pTNM stage: pT1b1 N0 (FIGO IB1).

D. Vagina, biopsy:

Negative for malignancy.

E. Left common iliac lymph nodes, excision:

Five lymph nodes, negative for metastatic disease.

F. Left external iliac lymph nodes, excision:

Four lymph nodes, negative for metastatic disease.

G. Left obturator lymph nodes, excision:

Two lymph nodes, negative for metastatic disease.

H. Right aortic/common iliac lymph nodes, excision:

Three lymph nodes, negative for metastatic disease.

I. Right external iliac lymph nodes, excision:

Seven lymph nodes, negative for metastatic disease.

J. Right obturator lymph nodes, excision:

Three lymph nodes, negative for metastatic disease.

Electronic Signature

ICD-O-3

carcinoma, squamous cell, NOS
8070/3

Site: cervix, NOS

C53.9

6-6-12

FD

Reviewed: [Signature]	Date Reviewed: 5/31/12	

W
6/5/12

[page 2 of 3]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Cervical CA.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right ovary and tube.
- B. Left ovary and tube.
- C. Radical hysterectomy.
- D. Vagina.
- E. Left common iliac.
- F. Left external iliac.
- G. Left obturator nodes.
- H. Right aortic/common iliac nodes.
- I. Right external iliac lymph nodes.
- J. Right obturator node.

SPECIMEN DATA

GROSS DESCRIPTION:

A. First container A is labeled I, right ovary tube. The specimen consists of an ovary with attached fallopian tube. The ovary measures 4 x 2 x 1 cm. The surface is gray-tan. There is white-tan excrescences noted on the ovarian surface covering a 1.5 x 1 cm. surface area. Sectioning there are cysts containing clear fluid measuring up to 0.5 cm. and reveals a corpus luteum measuring 0.5 cm. and corpus albicans measuring 0.2 cm. identified. The attached fallopian tube measures 4 cm. in length and 0.5 cm. in diameter. The surface is gray-tan to brown-tan. Through the center there is a metal clip identified. Sectioning there is no mature lesions identified.

Representative sections are submitted in cassettes labeled as follows: sections from ovary to include the excrescences in total in blocks 1-5; representative fallopian tube in block 6.

B. The second container B is labeled left ovary and tube the specimen consists of an ovary with attached fallopian tube. The ovary measures 3.5 x 3 x 1.5 cm. The surface is gray-tan to brown-tan. Sectioning there are multiple cysts containing clear serous fluid measuring up to 0.6 cm. as well as cysts containing hemorrhagic material measuring 1.5 cm. There are corpus lutei measuring up to 0.5 cm. The fallopian tube measures 3 cm. in length and 0.5 cm. in diameter. The surface is gray-tan to brown-tan. There is a metal clip identified within the segment of fallopian tube.

On sectioning the fallopian tube reveals mature lesions identified within the lumen. There is a paratubal cyst identified measuring 3 cm. containing clear fluid.

Representative sections are submitted in cassettes labeled as follows: ovary in blocks 1 and 2; fallopian tube and paratubal cysts in block 3.

C. Third container C is labeled radical hysterectomy. The specimen consists of a uterus with attached cervix. The uterus measures 7 x 6.8 x 6 cm. and weighs 143 grams. The serosal surface of the uterus is gray-tan to brown tan with slight hemorrhage. The cervix measures 4 cm. in length and 5 cm. in diameter. There is a rim of vaginal mucosa that is gray-tan to pink-tan. The ectocervical mucosa is gray-tan to brown-tan with hemorrhage. This margin has been inked. Sectioning the endocervical displays a brown tan nodular lesion measuring 1.7 x 1.7 cm. predominantly on the anterior wall that on sectioning extends into the underlying cervical wall approximately 1.2 cm. deep and is 1.5 cm. from the inked margin. It is 2.5 cm. from the vaginal margin. The endometrial cavity measures 5 cm. in length and 4 cm. from cornu to cornu. The lining measures 0.1 cm., light tan smooth glistening with focal hemorrhage. There is no lesion identified. The myometrium measures up to 2.8 cm. in greatest dimension, is gray-tan trabecular. A lesion is not identified.

Received with the specimen are three cassettes, one green, one yellow, one blue labeled

Representative sections are submitted in cassettes labeled : as follows: shaved sections through the vaginal cuff margin from 12 to 3:00 in block 1; 3 to 6:00 in block 2; 6 to 9:00 in block 3; 9 to 12:00 in block 4; sections from cervix from 12 to 3:00 to include the nodule in blocks 5 and 6; sections from 3 to 6:00 in blocks 8 and 9; 6 to 9:00 in blocks 10 and 11; sections from 9 to 12:00 includes nodule in blocks 12-14; left parametrium in block 15; right parametrium in block 16; right anterior in block 17; right posterior in block 18.

D. The fourth container D is labeled I vagina. The specimen consists of a piece of gray-brown soft tissue measuring 0.9 x 0.5 x 0.2 cm. The specimen is bisected and entirely submitted in a single cassette.

E. The fifth container E is labeled with the patient left common iliac. The specimen consists of a portion of fibroadipose tissue measuring 3.5 x 2.5 x 1 cm. Sectioning reveals five probable lymph nodes, 0.5 to 2.5 cm. All of the lymph nodes are entirely submitted in cassettes labeled as follows: two probable nodes in block 1; two probable nodes in block 2; one probable node bisected in block 3 and 4.

F. The sixth container F is labeled left external iliac. The specimen consists of a portion of fibroadipose tissue measuring 7 x 5.5 x 2 cm. Sectioning reveals four probable lymph nodes that measure from 0.8 to 2.6 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable node bisected in block 1; one probable node bisected in block 2; one probable node bisected in block 3; one

[page 3 of 3]
probable node sectioned in blocks 4-6.

G. The seventh container G is labeled with the patient name I, left obturator nodes. The specimen consists of a portion of fibroadipose tissue measuring 5 x 4.5 x 1 cm. Sectioning reveals two probable lymph nodes, 0.5 and 1.5 cm. in greatest dimension. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable node in block 1; one probable node bisected in blocks 2-3.

H. The eighth container H is labeled the patient right aortic and common iliac nodes. The specimen consists of a portion of fibroadipose tissue that measures 3.5 x 3 x 1 cm. Sectioning reveals three probable lymph nodes that measure from 0.7 to 1.8 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable node in block 1; one probable node bisected in blocks 2 and 3.

I. The ninth container I is labeled the patient name right external iliac lymph nodes. The specimen consists of a portion of fibroadipose tissue, 7 x 6.5 x 2 cm. Sectioning reveals seven possible lymph nodes that measure from 0.4 up to 2.5 cm.

Representative sections are submitted in cassettes labeled as follows: two probable nodes in block 1; two probable nodes in block 2; one probable node in block three; one probable node sectioned in blocks 4 and 5; one probable node sectioned in blocks 6 and 7.

J. The tenth container J is labeled with the patient I right obturator node and consists of a portion of fibroadipose tissue that measures 5 x 4.5 x 2 cm. Sectioning reveals three probable lymph nodes that measure from 0.5 to 2.5 cm. Sectioning reveals three possible lymph nodes, 0.5 to 1.7 cm. The lymph nodes are entirely submitted in cassettes labeled as follows: one probable node in block 1; one probable node sectioned in blocks 2 and 3; one probable node trisected in blocks 4-6.

Source: NCI Genomic Data Commons file 1ed31063-6a84-4bdc-8e35-33177928c37e (TCGA-FU-A3YQ.6BF77930-F8F4-41C5-86EF-EF43157BA6B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).